Somatic mutation profile of tumor specimen TCGA-DD-A4NH-01A (aliquot TCGA-DD-A4NH-01A-11D-A27I-10) from TCGA case TCGA-DD-A4NH, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 65.3 years (23,865 days).
Specimen TCGA-DD-A4NH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c0c73f0-5868-488e-a36c-646e1aa2cd2a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NH-10A (Blood Derived Normal), aliquot TCGA-DD-A4NH-10A-01D-A27I-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13befc23-4825-4b32-ac3a-b2f769d0d8f2

The open-access MAF lists 52 somatic variants for this specimen: 42 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 9, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1, Splice Site 1, In Frame Ins 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC2 | c.4183C>T p.Q1395* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as rs886041772, COSV51920558; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALG3 | c.1171C>T p.L391F | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV56612624; called by muse, mutect2, varscan2
- ANO4 | c.1819T>A p.S607T (on ENST00000392977 / NM_001286615.2; = p.S572T on NM_178826.4) | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1007246830, COSV54604275; called by muse, mutect2, varscan2
- ATP10D | c.331T>C p.W111R | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV56710193; called by muse, mutect2, varscan2
- BMP15 | c.496T>A p.S166T | Missense Mutation (SNP) | VAF 51/355 reads (14%) | SIFT tolerated (0.66); PolyPhen benign (0.258); catalogued as COSV53141135; called by muse, mutect2, varscan2
- C1QA | c.207C>A p.D69E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.288); catalogued as COSV65889885; called by muse, mutect2, varscan2
- COL7A1 | c.6865A>T p.K2289* | Nonsense Mutation (SNP) | VAF 18/137 reads (13%) | catalogued as COSV60398578; called by muse, mutect2, varscan2
- DCBLD2 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.999); catalogued as COSV58791267; called by muse, mutect2, varscan2
- DNASE1L1 | c.286A>G p.M96V | Missense Mutation (SNP) | VAF 53/264 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV50010711; called by muse, mutect2, varscan2
- DTX3 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 61/384 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as rs745554527, COSV54085489; called by muse, mutect2, varscan2
- DUOX2 | c.3436G>A p.A1146T | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.108); catalogued as rs757212555, COSV66532440; called by muse, mutect2, varscan2
- FRAS1 | c.1944C>A p.D648E | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.54); catalogued as COSV53627591; called by muse, mutect2, varscan2
- HRH3 | c.950C>T p.P317L | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs200015061, COSV58049410; called by muse, mutect2, varscan2
- IGSF10 | c.1283G>T p.W428L | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56788419; called by muse, mutect2, varscan2
- KBTBD8 | c.738A>T p.E246D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV55130199; called by muse, mutect2, varscan2
- KIR2DL3 | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 19/173 reads (11%) | catalogued as COSV100667567; called by muse, mutect2, varscan2
- LAMA5 | c.9524C>T p.S3175F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs772698717, COSV53365301; called by muse, mutect2, varscan2
- NLRP7 | c.1385G>A p.G462D | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as COSV60177646; called by muse, mutect2, varscan2
- OAT | c.1083G>A p.M361I | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV64347923; called by muse, mutect2, varscan2
- OR10H1 | c.860G>A p.S287N | Missense Mutation (SNP) | VAF 51/286 reads (18%) | SIFT tolerated (0.99); PolyPhen probably damaging (0.999); catalogued as COSV58472360; called by muse, mutect2, varscan2
- PLPP2 | c.113G>A p.C38Y | Missense Mutation (SNP) | VAF 35/250 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54121257; called by muse, mutect2, varscan2
- RBL2 | c.3418T>C p.*1140Rext*2 | Nonstop Mutation (SNP) | VAF 22/98 reads (22%) | catalogued as COSV50882242; called by muse, mutect2, varscan2
- RIBC1 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 57/316 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs782066146, COSV51448453; called by muse, mutect2, varscan2
- RIMS2 | c.995G>T p.R332L (on ENST00000666250 / NM_001348490.2; = p.R140L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51686773; called by muse, mutect2, varscan2
- RNF11 | c.40T>A p.S14T | Missense Mutation (SNP) | VAF 39/190 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.715); catalogued as COSV54376919; called by muse, mutect2, varscan2
- RPL7A | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs782417066, COSV59299052; called by muse, mutect2, varscan2
- SEZ6L2 | c.1669G>A p.V557M (on ENST00000308713 / NM_001114099.3; = p.V487M on NM_012410.4) | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as rs1161019964, COSV58099895; called by muse, mutect2, varscan2
- SPAG17 | c.1112T>A p.L371H | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60463111; called by muse, mutect2
- SYVN1 | c.346T>G p.F116V | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV53696125; called by muse, mutect2, varscan2
- TACC2 | c.2712G>T p.Q904H | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV57763320; called by muse, mutect2, varscan2
- TMEM218 | c.111-2A>T p.X37_splice | Splice Site (SNP) | VAF 9/31 reads (29%) | catalogued as COSV54445522; called by muse, mutect2, varscan2
- TMTC1 | c.332C>T p.P111L (on ENST00000539277 / NM_001193451.2; = p.P3L on NM_175861.3) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV55487403; called by muse, mutect2, varscan2
- VPS13A | c.8533A>C p.I2845L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV62433413; called by muse, varscan2
- ZNF454 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV60769308; called by muse, mutect2, varscan2
- ZNF780B | c.1861G>A p.A621T | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as COSV55465991; called by muse, mutect2, varscan2
- ADNP | c.2317_2318del p.K773Vfs*14 | Frame Shift Del (DEL) | VAF 37/187 reads (20%) | called by mutect2, pindel, varscan2
- AKT3 | c.480del p.V162Lfs*15 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- B4GALNT4 | c.566_573dup p.E192Tfs*7 | Frame Shift Ins (INS) | VAF 17/106 reads (16%) | called by mutect2, varscan2
- MLXIP | c.581_600del p.D194Afs*39 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | called by mutect2, varscan2
- PGS1 | c.585del p.H196Tfs*37 | Frame Shift Del (DEL) | VAF 41/164 reads (25%) | called by mutect2, pindel, varscan2
- RNASE4 | c.314_315insTCA p.K105delinsNQ | In Frame Ins (INS) | VAF 5/29 reads (17%) | called by mutect2, pindel, varscan2
- STAT5B | c.46dup p.H16Pfs*14 | Frame Shift Ins (INS) | VAF 40/222 reads (18%) | called by mutect2, pindel, varscan2
- DNAH7 | c.6177C>A p.P2059= | Silent (SNP) | VAF 39/186 reads (21%) | catalogued as rs1481811478, COSV56774565; called by muse, mutect2, varscan2
- GPRIN2 | c.882C>T p.A294= | Silent (SNP) | VAF 23/368 reads (6%) | catalogued as COSV65401676; called by muse, mutect2
- HIKESHI | c.318A>G p.P106= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as rs376891384; called by muse, mutect2, varscan2
- KIF21B | c.2766G>T p.R922= | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as COSV59761806; called by muse, mutect2
- MED27 | c.741C>T p.T247= | Silent (SNP) | VAF 30/165 reads (18%) | catalogued as COSV52603367; called by muse, mutect2, varscan2
- MPP1 | c.984G>A p.G328= | Silent (SNP) | VAF 56/326 reads (17%) | catalogued as rs782091002, COSV65729924; called by muse, mutect2, varscan2
- PCDHGC5 | c.1071C>T p.N357= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as COSV52748168, COSV52758583; called by muse, mutect2, varscan2
- SLC6A3 | c.1341C>T p.L447= | Silent (SNP) | VAF 33/180 reads (18%) | catalogued as COSV54366711; called by muse, mutect2, varscan2
- SNED1 | c.2718C>T p.L906= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as COSV60028410; called by muse, mutect2, varscan2
- AC244258.1 | n.311-5013T>A | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
